Somatic mutation profile of tumor specimen 0E0ZNW from CCDI case PBCVSG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0ZNW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17a92af1-bdb1-4429-a738-3994f9367668.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0ZOL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5de70c4c-2d58-4674-a5ff-471295643e54

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIG1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369456873; called by muse, mutect2, varscan2
- PPM1K | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.437); catalogued as rs769407666, COSV55796792; called by muse, mutect2
- VIPAS39 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 13/431 reads (3%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.001); called by muse, mutect2
